Somatic mutation profile of tumor specimen TCGA-29-1764-01A (aliquot TCGA-29-1764-01A-01W-0633-09) from TCGA case TCGA-29-1764, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 49.3 years (18,012 days).
Specimen TCGA-29-1764-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1c6579d-b95b-4166-83f3-9100fcae89d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1764-10A (Blood Derived Normal), aliquot TCGA-29-1764-10A-01W-0634-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19943c1c-4562-46d1-8708-4a135c737d1d

The open-access MAF lists 100 somatic variants for this specimen: 79 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 18, Frame Shift Del 4, Nonsense Mutation 4, Splice Site 2, RNA 1, Translation Start Site 1, Intron 1, In Frame Del 1, Splice Region 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 74/145 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.1166C>A p.P389H | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV70027907; called by muse, mutect2, varscan2
- ABLIM2 | c.483G>C p.K161N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV56412924; called by muse, mutect2, varscan2
- ACSM2A | c.1648C>A p.L550M (on ENST00000219054; = p.L471M on NM_001308169.2) | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs571837503, COSV54582793, COSV54584298; called by muse, mutect2, varscan2
- AEBP1 | c.2415G>C p.E805D | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV56261713; called by muse, mutect2, varscan2
- AK5 | c.1055A>G p.D352G (on ENST00000354567 / NM_174858.3; = p.D326G on NM_012093.4) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV60982615; called by muse, mutect2, varscan2
- ANKRD35 | c.1820G>A p.G607D | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV62911751; called by muse, mutect2, varscan2
- APOB | c.7787C>G p.T2596S | Missense Mutation (SNP) | VAF 99/364 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV51955529; called by muse, mutect2, varscan2
- ATP5F1E | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1009913282, COSV53888580; called by muse, mutect2, varscan2
- ATP8A2 | c.2479G>A p.G827R | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54978655; called by muse, mutect2, varscan2
- BCL9 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.284); catalogued as COSV52351009; called by muse, mutect2, varscan2
- CBWD1 | c.203G>T p.S68I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV58703522; called by mutect2, varscan2
- CCDC73 | c.1353T>G p.F451L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV58805701; called by muse, mutect2, varscan2
- CENPC | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV56626818; called by muse, mutect2, varscan2
- CEP170 | c.3101C>G p.S1034C | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV60505800; called by muse, mutect2
- CHAT | c.390G>A p.G130= | Splice Region (SNP) | VAF 8/28 reads (29%) | catalogued as COSV60319470, COSV60334397; called by muse, mutect2, varscan2
- COL22A1 | c.952C>A p.Q318K | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100278635, COSV57362896; called by muse, mutect2, varscan2
- CTTNBP2NL | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV54745720; called by muse, mutect2
- CYP4A11 | c.207C>G p.D69E | Missense Mutation (SNP) | VAF 93/743 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV60226001; called by muse, mutect2, varscan2
- CYP4F3 | c.978G>A p.M326I | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55412917, COSV99658207; called by muse, mutect2
- DNAJC6 | c.94A>G p.R32G | Missense Mutation (SNP) | VAF 50/345 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV54782674; called by muse, mutect2, varscan2
- E2F2 | c.1121T>A p.L374Q | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV62276856; called by muse, mutect2
- EPHA3 | c.865A>T p.K289* | Nonsense Mutation (SNP) | VAF 13/178 reads (7%) | catalogued as COSV100345422; called by muse, mutect2
- ERBB3 | c.3655G>A p.E1219K | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV57262333; called by muse, mutect2, varscan2
- EXOSC10 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV100442545; called by muse, mutect2
- FN1 | c.2374C>G p.Q792E | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs745416782, COSV60565526; called by muse, mutect2, varscan2
- FREM1 | c.5718C>G p.I1906M | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV101084576; called by muse, mutect2
- GARNL3 | c.3039G>C p.K1013N | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV59231129; called by muse, mutect2, varscan2
- HECTD1 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV67949516; called by muse, mutect2, varscan2
- HSPG2 | c.1156T>G p.F386V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs761129050, COSV65930988; called by muse, mutect2, varscan2
- IMPG1 | c.497+2C>G p.X166_splice | Splice Site (SNP) | VAF 8/174 reads (5%) | catalogued as COSV100886401; called by muse, mutect2
- KIAA2026 | c.3229G>C p.D1077H | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV67357846, COSV67358113; called by muse, mutect2, varscan2
- KMT2C | c.1799G>A p.S600N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV100072138; called by muse, mutect2, varscan2
- LENEP | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 40/107 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as COSV52700462; called by muse, mutect2, varscan2
- LRRC30 | c.882C>A p.Y294* | Nonsense Mutation (SNP) | VAF 51/141 reads (36%) | catalogued as COSV67302421; called by muse, mutect2, varscan2
- LRRC37B | c.754C>G p.P252A | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.292); catalogued as COSV58955389; called by muse, mutect2, varscan2
- LY75 | c.2755C>G p.P919A | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV55113812; called by muse, varscan2
- MAST2 | c.2307G>C p.E769D | Missense Mutation (SNP) | VAF 5/113 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.796); catalogued as COSV63621532; called by muse, mutect2
- MROH7 | c.332A>C p.D111A | Missense Mutation (SNP) | VAF 38/842 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV100273512; called by muse, mutect2
- MYO7A | c.5752G>T p.V1918L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV68687520; called by muse, mutect2
- NIBAN1 | c.1987C>A p.P663T | Missense Mutation (SNP) | VAF 104/218 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV62288214; called by muse, mutect2, varscan2
- NLRP4 | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149428225; called by muse, mutect2, varscan2
- OR4K2 | c.437T>A p.V146E | Missense Mutation (SNP) | VAF 50/429 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV53851981; called by muse, mutect2, varscan2
- OVCH1 | c.326T>C p.L109P | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV58968747; called by muse, mutect2, varscan2
- PABPC1 | c.1180A>C p.N394H | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV59408511; called by muse, mutect2, varscan2
- PBK | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV100107381; called by muse, mutect2
- PLEKHA3 | c.776-2A>G p.X259_splice | Splice Site (SNP) | VAF 23/193 reads (12%) | catalogued as COSV52296906; called by muse, mutect2, varscan2
- RANBP17 | c.1134T>G p.Y378* | Nonsense Mutation (SNP) | VAF 84/144 reads (58%) | catalogued as COSV66658168; called by muse, mutect2, varscan2
- RB1CC1 | c.1649G>T p.R550L | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.552); catalogued as COSV50279553; called by muse, mutect2
- RBM39 | c.1148G>C p.G383A | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as COSV53618331; called by muse, mutect2, varscan2
- RO60 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV66475190; called by muse, mutect2, varscan2
- SEC14L5 | c.961C>A p.Q321K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.281); catalogued as COSV52042520; called by muse, mutect2, varscan2
- SERPINB13 | c.597G>C p.E199D | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV54027751, COSV54030788, COSV54031308; called by muse, mutect2, varscan2
- SERPINB4 | c.1138A>T p.S380C | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV61986385; called by muse, mutect2, varscan2
- SERTAD4 | c.335C>A p.S112Y | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65400368; called by muse, mutect2, varscan2
- SLC39A12 | c.1202T>A p.L401* | Nonsense Mutation (SNP) | VAF 21/109 reads (19%) | catalogued as COSV66202909; called by muse, mutect2, varscan2
- SLC6A3 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs1277034664, COSV54370193; called by muse, mutect2, varscan2
- SRSF1 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV51966000, COSV51966647; called by muse, mutect2, varscan2
- TECTA | c.2269A>G p.K757E | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.818); catalogued as COSV50822672; called by muse, mutect2, varscan2
- TMEM74 | c.423G>C p.W141C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.871); catalogued as COSV52465009; called by muse, mutect2
- TOX3 | c.716A>G p.K239R | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV54874284; called by muse, mutect2, varscan2
- TRIOBP | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs1270705836, COSV60384604, COSV60385285; called by muse, mutect2, varscan2
- TSHZ1 | c.1978G>C p.E660Q (on ENST00000580243 / NM_001308210.2; = p.E615Q on NM_005786.6) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.193); catalogued as COSV100433708; called by muse, mutect2
- TTC39B | c.1127C>A p.A376E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs143112996, COSV52617585; called by muse, mutect2, varscan2
- UGT2A1 | c.325C>G p.Q109E | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.096); catalogued as COSV54147141; called by muse, mutect2, varscan2
- VAV2 | c.1013A>T p.K338I (on ENST00000371850 / NM_001134398.2; = p.K333I on NM_003371.4) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64085797; called by muse, mutect2, varscan2
- ZFYVE1 | c.625A>G p.K209E | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV59613477, COSV59613610; called by muse, varscan2
- ZNF560 | c.1906G>C p.A636P | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV100038656; called by muse, mutect2
- ZNF777 | c.394C>G p.P132A | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV56100607; called by muse, mutect2, varscan2
- ACTR1A | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BRD7 | c.552del p.I185Sfs*9 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | called by mutect2, pindel, varscan2
- COL1A1 | c.2450dup p.G818Wfs*3 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- FLG2 | c.3465_3489del p.Q1155Hfs*64 | Frame Shift Del (DEL) | VAF 80/318 reads (25%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.3061_3092del p.H1021Ifs*21 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- NCEH1 | c.319T>C p.W107R (on ENST00000538775; = p.W75R on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- NPTN | c.1004G>A p.S335N | Missense Mutation (SNP) | VAF 5/122 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PKHD1L1 | c.6434del p.M2145Rfs*71 | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | called by mutect2, pindel, varscan2
- RGPD1 | c.4366T>A p.S1456T (on ENST00000409776; = p.S1464T on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.88); PolyPhen benign (0); called by mutect2, varscan2
- TCAF1 | c.297_305del p.P100_A102del | In Frame Del (DEL) | VAF 38/176 reads (22%) | called by mutect2, pindel, varscan2
- ASXL2 | c.1176G>A p.L392= | Silent (SNP) | VAF 115/333 reads (35%) | catalogued as COSV55468907; called by muse, mutect2, varscan2
- CHD5 | c.3967C>T p.L1323= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99313698; called by muse, mutect2
- CTSG | c.432G>C p.V144= | Silent (SNP) | VAF 22/152 reads (14%) | catalogued as COSV53537094; called by muse, mutect2, varscan2
- DIABLO | c.240G>A p.L80= (on ENST00000443649 / NM_001278303.1; = p.L153= on NM_019887.6) | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV57337691; called by muse, mutect2, varscan2
- DMBT1 | c.3481A>C p.R1161= (on ENST00000338354 / NM_001377530.1; = p.R662= on NM_004406.3) | Silent (SNP) | VAF 197/343 reads (57%) | catalogued as COSV57565657; called by muse, mutect2, varscan2
- EYS | c.1089A>C p.T363= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs370471214; called by muse, mutect2, varscan2
- FSHR | c.78T>A p.S26= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV58616749; called by muse, mutect2, varscan2
- HCFC1 | c.2202C>T p.T734= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV60078486; called by muse, mutect2, varscan2
- MPG | c.627C>G p.L209= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV54739735; called by muse, mutect2, varscan2
- NDE1 | c.252G>A p.V84= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as rs911529614, COSV61277723; called by muse, mutect2, varscan2
- NRCAM | c.2070G>A p.K690= (on ENST00000379028 / NM_001371124.1; = p.K674= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV61050796; called by muse, mutect2, varscan2
- OR7D4 | c.834C>T p.Y278= | Silent (SNP) | VAF 76/243 reads (31%) | catalogued as rs771972062, COSV58071421; called by muse, mutect2, varscan2
- PAK1 | c.1236A>C p.A412= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV53702122; called by muse, mutect2, varscan2
- PTPRZ1 | c.2415G>A p.V805= | Silent (SNP) | VAF 49/423 reads (12%) | catalogued as COSV66446638; called by muse, mutect2, varscan2
- SEL1L2 | c.1995A>G p.P665= | Silent (SNP) | VAF 19/177 reads (11%) | catalogued as COSV53159122; called by muse, mutect2, varscan2
- SIPA1L1 | c.5382A>G p.T1794= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as COSV62174241; called by muse, mutect2, varscan2
- SLC6A18 | c.993C>T p.I331= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV57254841; called by muse, mutect2, varscan2
- TG | c.2226G>A p.V742= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as COSV55096666; called by muse, mutect2, varscan2
- AL109984.1 | chr20:52097098 A>C | 3'Flank (SNP) | VAF 8/32 reads (25%) | catalogued as COSV63755099; called by muse, mutect2, varscan2
- GBA3 | c.59-8236G>A | Intron (SNP) | VAF 73/376 reads (19%) | catalogued as rs375288423; called by muse, mutect2, varscan2
- NBPF25P | n.1728G>A | RNA (SNP) | VAF 46/646 reads (7%) | called by muse, mutect2
